Somatic mutation profile of tumor specimen MMRF_1861_1_BM_CD138pos (aliquot MMRF_1861_1_BM_CD138pos_T1_KBS5U_L07235) from MMRF case MMRF_1861, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.0 years (26,303 days).
Specimen MMRF_1861_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91ad5753-32b0-42c4-934d-7bc25cf1f3ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1861_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1861_1_PB_WBC_C3_KBS5U_L07236; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/174aef5c-068d-4e35-8222-fa391d8c536e

The open-access MAF lists 104 somatic variants for this specimen: 45 protein-altering or splice-affecting, 21 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 24, Silent 21, Intron 10, Frame Shift Ins 2, Splice Region 2, 3'Flank 2, Splice Site 2, Nonsense Mutation 2, In Frame Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ACACB | c.5178+8C>T | Splice Region (SNP) | VAF 52/160 reads (33%) | catalogued as rs535663467; called by muse, mutect2, varscan2
- CD83 | c.153G>A p.K51= | Splice Region (SNP) | VAF 28/90 reads (31%) | catalogued as rs528134602; called by muse, mutect2, varscan2
- CH25H | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.089); catalogued as COSV100897389; called by muse, mutect2, varscan2
- ESRRG | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs775763985, COSV63149076; called by muse, mutect2, varscan2
- FLNC | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as COSV100368098; called by muse, mutect2, varscan2
- GALNT13 | c.1639T>G p.W547G | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67225496; called by muse, mutect2
- GSTA3 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as rs370423929; called by muse, mutect2, varscan2
- KRT5 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs141279000; ClinVar: likely benign; called by muse, mutect2, varscan2
- MOS | c.176A>C p.Q59P | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100322835; called by muse, mutect2, varscan2
- PPP4R1 | c.760-2A>G p.X254_splice (on ENST00000400556 / NM_001042388.3; = p.X237_splice on NM_005134.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 50/285 reads (18%) | catalogued as rs752998481; called by muse, mutect2
- SGSM1 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376508684; called by muse, mutect2, varscan2
- SORL1 | c.4052G>A p.G1351D | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52754966; called by muse, mutect2, varscan2
- TMEM132C | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316723217; called by muse, mutect2, varscan2
- TMEM145 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 22/164 reads (13%) | catalogued as rs755937975, COSV56627601; called by muse, mutect2, varscan2
- ZFP30 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 29/193 reads (15%) | catalogued as rs563719737; called by muse, mutect2, varscan2
- ZNF607 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs570323220, COSV62206046, COSV67696082; called by muse, mutect2, varscan2
- ANKRD22 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CCAR1 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CETN3 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 56/359 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD6 | c.4923A>C p.E1641D | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CHI3L1 | c.1108T>C p.F370L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- FAM186B | c.2007G>C p.Q669H | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- KLHL41 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.014); called by muse, mutect2
- LTF | c.1942G>T p.D648Y | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2
- MAPT | c.1724C>T p.P575L (on ENST00000262410 / NM_001377265.1; = p.P183L on NM_005910.5) | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MASP1 | c.1219A>T p.N407Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- MYH10 | c.1402-1G>A p.X468_splice | Splice Site (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- NODAL | c.887T>A p.I296N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PDLIM1 | c.368G>T p.S123I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PHACTR4 | c.521C>G p.P174R (on ENST00000373839 / NM_001350159.2; = p.P184R on NM_023923.4) | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- PRDM5 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRF1 | c.844A>G p.K282E | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.17); called by muse, mutect2
- RUSC2 | c.4010G>T p.R1337L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC6A8 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SMC4 | c.253dup p.T85Nfs*22 | Frame Shift Ins (INS) | VAF 50/203 reads (25%) | called by mutect2, pindel, varscan2
- SPAM1 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 108/275 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPEF2 | c.4227dup p.L1410Ifs*3 | Frame Shift Ins (INS) | VAF 15/95 reads (16%) | called by mutect2, pindel, varscan2
- SSTR5 | c.781T>C p.W261R | Missense Mutation (SNP) | VAF 132/206 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STPG2 | c.1241G>A p.C414Y | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TDRD6 | c.5321A>T p.D1774V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TECTB | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TMEM63C | c.1261_1272del p.F421_L424del | In Frame Del (DEL) | VAF 27/158 reads (17%) | called by mutect2, pindel, varscan2
- TRAFD1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TYRP1 | c.1235A>G p.D412G | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- AGAP1 | c.2046C>T p.N682= (on ENST00000304032 / NM_001037131.3; = p.N629= on NM_014914.5) | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as rs373756580; called by muse, mutect2, varscan2
- ATP2C1 | c.1827A>G p.Q609= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs1209738209; called by muse, mutect2, varscan2
- BTN3A1 | c.63T>C p.L21= | Silent (SNP) | VAF 43/157 reads (27%) | called by muse, mutect2, varscan2
- CADM3 | c.304C>T p.L102= (on ENST00000368125 / NM_001127173.3; = p.L136= on NM_021189.5) | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- CDH20 | c.2091G>A p.T697= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs1255455571, COSV99404138; called by muse, mutect2, varscan2
- COL5A1 | c.1476C>A p.V492= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- COL6A3 | c.4104G>A p.T1368= | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as rs777649526; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DUSP19 | c.37C>A p.R13= | Silent (SNP) | VAF 26/198 reads (13%) | catalogued as COSV100700339; called by muse, mutect2, varscan2
- ENPP6 | c.945T>C p.F315= | Silent (SNP) | VAF 68/217 reads (31%) | called by muse, mutect2, varscan2
- EYS | c.6756T>C p.V2252= | Silent (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- HTR1D | c.108G>A p.A36= | Silent (SNP) | VAF 33/174 reads (19%) | catalogued as rs1184721925, COSV58447804; called by muse, mutect2, varscan2
- MUC5B | c.9315C>A p.T3105= | Silent (SNP) | VAF 34/284 reads (12%) | catalogued as rs375109401; called by muse, mutect2, varscan2
- NKD2 | c.951G>A p.L317= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- PCDH17 | c.633C>G p.L211= | Silent (SNP) | VAF 21/182 reads (12%) | catalogued as rs749143274, COSV64974215; called by muse, mutect2, varscan2
- SLC10A4 | c.808C>T p.L270= | Silent (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2, varscan2
- TMEM198 | c.520C>T p.L174= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1020188846; called by muse, mutect2, varscan2
- TOGARAM2 | c.2187T>C p.S729= | Silent (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- VSTM5 | c.96G>A p.Q32= | Silent (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2, varscan2
- WBP4 | c.861T>A p.T287= | Silent (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- WNT7B | c.426C>T p.N142= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs149350399; called by muse, mutect2
- ZFP92 | c.609C>T p.S203= | Silent (SNP) | VAF 90/150 reads (60%) | catalogued as rs782113683, COSV100100474; called by muse, mutect2, varscan2
- ARID5B | c.*2240G>A | 3'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- BBOF1 | c.*51G>T | 3'UTR (SNP) | VAF 10/291 reads (3%) | called by muse, mutect2
- BCHE | c.1685-5158G>A | Intron (SNP) | VAF 63/269 reads (23%) | catalogued as rs1331366778; called by muse, mutect2, varscan2
- C15orf40 | chr15:82990647 G>T | 3'Flank (SNP) | VAF 248/491 reads (51%) | called by muse, mutect2, varscan2
- CACNA1E | c.*3233G>A | 3'UTR (SNP) | VAF 24/121 reads (20%) | called by muse, mutect2, varscan2
- CDH17 | c.*589C>T | 3'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- CEBPE | c.*130C>T | 3'UTR (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- DENND5A | c.1907-297C>T | Intron (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- DGKB | c.*1872A>G | 3'UTR (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- FBXO39 | c.*201C>T | 3'UTR (SNP) | VAF 9/46 reads (20%) | catalogued as rs1035264231; called by muse, mutect2, varscan2
- FGF13 | c.*973A>C | 3'UTR (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- FOXK1 | c.*4786C>T | 3'UTR (SNP) | VAF 6/90 reads (7%) | catalogued as rs1475048316; called by muse, mutect2
- GPR1 | c.*744T>C | 3'UTR (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- GRID1 | c.*1624C>T | 3'UTR (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- HSPA12A | c.*2969C>A | 3'UTR (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- IGLV3-10 | c.-17G>A | 5'UTR (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- IQSEC1 | c.*150G>A | 3'UTR (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- KLRC1 | c.283+27G>A | Intron (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- LRFN2 | c.*20C>T | 3'UTR (SNP) | VAF 11/69 reads (16%) | catalogued as rs1328824009; called by muse, mutect2, varscan2
- LRRC28 | c.*711T>A | 3'UTR (SNP) | VAF 17/127 reads (13%) | catalogued as rs1220998197; called by muse, mutect2, varscan2
- LTB | c.163-119G>A | Intron (SNP) | VAF 83/275 reads (30%) | catalogued as rs41273244, COSV53000283, COSV53001753; called by muse, mutect2, varscan2
- MAP3K2 | c.*6970del | 3'UTR (DEL) | VAF 17/95 reads (18%) | called by mutect2, pindel, varscan2
- MMAA | c.562+47_562+48del | Intron (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- MRS2 | c.*1380A>G | 3'UTR (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- NOS1 | c.*3658G>T | 3'UTR (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- NPY2R | c.*1929T>A | 3'UTR (SNP) | VAF 11/58 reads (19%) | called by mutect2, varscan2
- NTRK2 | c.1397-54005G>A | Intron (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- NTRK2 | c.1585+6079dup | Intron (INS) | VAF 32/77 reads (42%) | catalogued as rs973886630; called by mutect2, varscan2
- PAX9 | c.*2560T>G | 3'UTR (SNP) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- PCTP | c.580-89G>T | Intron (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- PPME1 | c.645-37T>C | Intron (SNP) | VAF 18/101 reads (18%) | catalogued as rs1043174301; called by muse, mutect2, varscan2
- PRKAB2 | c.*701C>T | 3'UTR (SNP) | VAF 15/45 reads (33%) | catalogued as rs1253770582; called by muse, mutect2, varscan2
- PRRG4 | c.*3875C>T | 3'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- PTGES3L | chr17:42968774 C>G | 3'Flank (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- SLC25A51P4 | n.1463+83dup | Intron (INS) | VAF 21/184 reads (11%) | catalogued as rs1176004417; called by mutect2, varscan2
- SNORD115-48 | n.17G>A | RNA (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
- UBXN10 | c.*29G>C | 3'UTR (SNP) | VAF 9/118 reads (8%) | called by muse, mutect2
- VSTM2A | c.*527_*531del | 3'UTR (DEL) | VAF 17/93 reads (18%) | catalogued as rs1009481433; called by mutect2, pindel, varscan2
